Somatic mutation profile of tumor specimen 0DWM1C from CCDI case PBCNYJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.2 years (1,162 days).
Specimen 0DWM1C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65514e71-4ea2-4c06-8a94-645eadd19c0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWLYP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66cedcb3-0766-47d8-a4ac-41ce7412d0e5

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD17C | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 229/605 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs1342510818, COSV51917047; called by muse, mutect2, varscan2
- FLNA | c.3615C>T p.A1205= | Silent (SNP) | VAF 114/431 reads (26%) | catalogued as rs1557177719; called by muse, mutect2, varscan2
